Gene-level copy-number profile of tumor specimen TCGA-AP-A053-01A from TCGA case TCGA-AP-A053, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AP-A053-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.65e9e7d4-38f5-4690-835d-298b81b5971d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AP-A053-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9612a6af-49c7-4e60-913a-cc6b29959a3d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,867; copy number 2: 43,857; copy number 3: 4,935; copy number 4: 463; copy number 5: 208; copy number 6: 97; copy number 7: 145; copy number 8: 26; copy number 9: 69; copy number 10: 7; copy number 11: 6; copy number 14: 106; copy number 25: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AP-A053-01): tumor purity 0.92, ploidy 2, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 550 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,926,263–151,459,494, 35 genes, copy number 5: SETDB1, CERS2, AL590133.2, AL590133.1, ANXA9, MINDY1, PRUNE1, RNU6-884P, BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A, PSMD4, ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25.
- chr2:188,227,189–188,276,844, 2 genes, copy number 5: AC104131.1, RNA5SP114.
- chr2:188,297,492–188,297,588, 1 gene, copy number 5: MIR561.
- chr3:168,858,659–169,038,416, 5 genes, copy number 7: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr10:23,694,746–24,547,848, 4 genes, copy number 5 (within-gene range 2–5): KIAA1217, NUP35P1, AC063961.1, MIR603.
- chr10:70,597,348–70,602,759, 1 gene, copy number 7: PRF1.
- chr11:57,299,638–58,761,053, 77 genes, copy number 9–14 (within-gene range 1–14) (broad region; genes not listed).
- chr11:59,560,298–60,417,756, 35 genes, copy number 8–14 (within-gene range 1–14): LINC02739, AP000442.1, OSBP, MIR3162, PATL1, AP000640.2, RN7SKP192, OR10V1, STX3, OR10Y1P, OR10V3P, OR10V2P, AP000640.1, FABP5P7, MRPL16, CBLIF, TCN1, OOSP3, SRD5A3P1, OOSP1, AP000790.1, OOSP4A, OOSP4B, OOSP2, MS4A3, AP000790.2, MS4A2, LINC02705, MS4A6A, MS4A4A, MS4A4E, MIR6503, MS4A6E, MS4A7, MS4A14.
- chr14:76,826,372–76,924,649, 4 genes, copy number 6 (within-gene range 2–6): LRRC74A, RPL22P2, RN7SKP17, AF111169.2.
- chr14:77,131,270–77,142,996, 2 genes, copy number 5: ZDHHC22, AC007375.3.
- chr17:39,546,104–39,997,959, 23 genes, copy number 11–25: RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3.
- chr17:55,526,964–55,872,939, 6 genes, copy number 5: AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1.
- chr17:75,525,080–75,879,546, 18 genes, copy number 6 (within-gene range 4–6): LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738, UNK, AC087289.1, UNC13D, WBP2, TRIM47, AC087289.5.
- chr17:76,142,465–76,726,799, 36 genes, copy number 5 (within-gene range 3–5): RNF157, ATP5MGP6, ATF4P3, UBALD2, QRICH2, PRPSAP1, Y_RNA, RNU6-24P, AC090699.1, SPHK1, UBE2O, RPL7P49, AANAT, RHBDF2, CYGB, PRCD, AC015802.4, AC015802.3, AC015802.5, SNHG16, SNORD1C, SNORD1B, SNORD1A, AC015802.6, ST6GALNAC2, AC015802.1, AC015802.2, AC015802.7, ST6GALNAC1, RNU6-227P, AC005837.1, MXRA7, RNY4P36, AC005837.4, JMJD6, AC005837.3.
- chr17:77,877,330–83,095,122, 235 genes, copy number 7–14 (broad region; genes not listed).
- chr18:52,223,078–52,339,025, 3 genes, copy number 5: AC016383.3, AC016383.2, AC016383.1.
- chr18:52,409,042–52,419,644, 2 genes, copy number 5: AC011155.1, VN1R76P.
- chr19:8,206,736–8,843,340, 32 genes, copy number 6: CERS4, AC022146.2, CD320, AC010323.1, NDUFA7, RPS28, KANK3, AC010323.2, ANGPTL4, RAB11B-AS1, MIR4999, RAB11B, MARCHF2, AC136469.1, AC136469.2, HNRNPM, PRAM1, ZNF414, MYO1F, AC092316.1, ADAMTS10, AC130469.1, NFILZ, AC243312.1, ACTL9, OR2Z1, RPL23AP78, AC012616.1, ZNF558, AC008734.1, MBD3L1, AC008734.2.
- chr19:19,063,994–19,663,676, 29 genes, copy number 5 (within-gene range 4–5): SLC25A42, TMEM161A, MEF2B, BORCS8-MEF2B, BORCS8, RFXANK, NR2C2AP, NCAN, RNU6-1028P, AC138430.1, HAPLN4, AC138430.2, TM6SF2, SUGP1, MAU2, GATAD2A, AC092067.1, MIR640, TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2, PBX4, PHF5CP, AC002306.1, LPAR2, GMIP, ATP13A1.

Autosomal genes at a single copy (total copy number 1): 7,731. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
